Surgical pathology report (de-identified scan), TCGA case TCGA-BA-A6DG, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-BA-A6DG-01A (Primary Tumor).

SURGICAL PATHOLOGY

Case Number :

Diagnosis:

Left tongue, biopsy

- Invasive moderately differentiated squamous cell carcinoma.
- P16 immunostain and in situ hybridization for high risk HPV are both negative.

Clinical History:

-year-old male with left tongue cancer. Please do HPV and P16 staining.

Gross Description:

Received is one appropriately labeled container, additionally labeled "left tongue" and holds multiple fragments of tan/pink soft tissue, 1.7 x 1.5 x 0.4 cm in aggregate, submitted in A1-A2,

ICD-0-3

Carcinoma, squamous cell, NOS 8070/3

Site: tongue, NOS C02.9

hw
5/24/13

Criteria	hw 5/15/13	Yes	No

Source: NCI Genomic Data Commons file af7579ce-2442-441c-a544-c955207ea61c (TCGA-BA-A6DG.306B1796-60A1-4F5F-8123-57CBEB0283D5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).